Somatic mutation profile of tumor specimen MP2PRT-PAPCNZ-TMP1-A (aliquot MP2PRT-PAPCNZ-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCNZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,207 days).
Specimen MP2PRT-PAPCNZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) badcb9d8-0754-425f-9e2a-e73c5d59cde3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCNZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCNZ-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7463cebf-e417-4f0c-ac96-aa2bf9661aea

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 3'Flank 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 59/188 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV57839936; called by muse, mutect2, varscan2
- ARHGEF11 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 113/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145549282; called by muse, mutect2, varscan2
- ASTN2 | c.1290C>A p.S430R (on ENST00000313400 / NM_001365069.1; = p.S379R on NM_014010.5) | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57774773; called by muse, mutect2
- DKK3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100484871; called by muse, mutect2, varscan2
- KCND2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.375); catalogued as rs35460901; called by muse, mutect2, varscan2
- LDLRAD3 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs372710536; called by muse, mutect2, varscan2
- TMC2 | c.2416G>C p.V806L | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100727439; called by muse, mutect2
- TPSG1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 164/382 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772861611, COSV52354516; called by muse, mutect2, varscan2
- ZFYVE28 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 150/389 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1427943499; called by muse, varscan2
- H2AC17 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 53/337 reads (16%) | called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506984 TTTCACACTGTGTATCTTGCACAG>CCTTT | Missense Mutation (DEL) | VAF 73/97 reads (75%) | called by pindel, varscan2*
- ZDHHC8 | c.2071G>A p.V691I | Missense Mutation (SNP) | VAF 160/399 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNM1 | c.72C>A p.G24= | Silent (SNP) | VAF 162/357 reads (45%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins GGTG | 3'Flank (INS) | VAF 30/94 reads (32%) | called by pindel, varscan2
